Gene-level copy-number profile of specimen HCM-BROD-0829-C71-85A from HCMI case HCM-BROD-0829-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.5 years (24,277 days).
Specimen HCM-BROD-0829-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d4c96dee-79e0-43c2-ba6c-86f6e6343644.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0829-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/fcc86fcc-4ebe-4d0e-9e64-58ecc3b2648a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,607; copy number 2: 49,885; copy number 3: 3,292; copy number 4: 2; copy number 21: 122; copy number 43: 1; copy number 45: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 128 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,475,806–205,602,918, 66 genes, copy number 21 (within-gene range 2–21) (broad region; genes not listed).
- chr1:211,326,615–213,274,774, 56 genes, copy number 21: TRAF5, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1, NENF, LINC02771, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A, AL590648.1, LINC02773, BATF3, NSL1, TATDN3, AC104333.3, SPATA45, FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1, VASH2, ANGEL2, RPS6KC1.
- chr4:54,229,280–54,298,245, 1 gene, copy number 43 (within-gene range 2–43): PDGFRA.
- chr4:54,836,041–55,032,071, 5 genes, copy number 45: AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P.

Autosomal genes at a single copy (total copy number 1): 2,751. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
